Gene-level copy-number profile of tumor specimen TCGA-DD-AACE-01A from TCGA case TCGA-DD-AACE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.2 years (22,727 days).
Specimen TCGA-DD-AACE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b4217dee-9baa-4740-ab3b-688044061b33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0caf037d-3136-47f0-b490-5bca2f52b09c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,410; copy number 2: 21,456; copy number 3: 27,164; copy number 4: 2,699; copy number 5: 2,341; copy number 6: 1,970; copy number 7: 727; copy number 8: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACE-01A-11D-A40Q-01): tumor purity 0.75, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 776 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,304,942–4,583,871, 1 gene, copy number 7 (within-gene range 6–7): AL162718.1.
- chr6:4,427,963–10,222,161, 86 genes, copy number 7 (broad region; genes not listed).
- chr6:18,522,735–18,674,001, 1 gene, copy number 7 (within-gene range 6–7): MIR548A1HG.
- chr6:19,143,695–20,042,940, 11 genes, copy number 7: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1.
- chr6:45,573,346–49,950,265, 61 genes, copy number 7 (broad region; genes not listed).
- chr6:53,561,289–55,402,493, 24 genes, copy number 7 (within-gene range 6–7): AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL.
- chr13:64,958,097–114,337,626, 592 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 989. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
